Gene-level copy-number profile of tumor specimen TCGA-OU-A5PI-01A from TCGA case TCGA-OU-A5PI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.4 years (19,492 days).
Specimen TCGA-OU-A5PI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.d42d916b-0232-44e0-8fb8-97d3da177be7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OU-A5PI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16164daf-7b94-4533-b499-6bf9b424dd96

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 4; copy number 2: 29,639; copy number 3: 15; copy number 4: 27,026; copy number 5: 35; copy number 6: 722; copy number 7: 2,332; copy number 8: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OU-A5PI-01A-12D-A29H-01): tumor purity 0.89, ploidy 1.54, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:81,967,079–82,005,700, 2 genes: RN7SL201P, AC079896.1.
- chr17:17,616,043–17,837,011, 11 genes: AC020558.5, SMCR2, AC020558.3, AC020558.4, RAI1, RAI1-AS1, SMCR5, AC122129.2, SREBF1, MIR6777, MIR33B.
- chr17:60,810,165–61,070,356, 6 genes: KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74.
- chr18:50,959,267–51,085,045, 4 genes: Y_RNA, ELAC1, AC091551.1, SMAD4.
- chr22:28,794,555–28,848,559, 4 genes: XBP1, Z93930.2, Z93930.3, Z93930.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,109 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:122,739,999–123,274,136, 7 genes, copy number 7 (within-gene range 4–7): HSPBAP1, SLC49A4, LINC02035, SEMA5B, PDIA5, MIR7110, SEC22A.
- chr4:6,648,695–7,057,952, 18 genes, copy number 7: LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B.
- chr5:50,396,192–181,342,213, 2,275 genes, copy number 7 (broad region; genes not listed).
- chr16:69,187,129–69,309,052, 1 gene, copy number 7 (within-gene range 4–7): SNTB2.
- chr16:69,240,549–69,466,264, 14 genes, copy number 7: AC026474.1, AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2.
- chr16:69,565,808–69,565,868, 1 gene, copy number 7: MIR1538.
- chr19:2,754,715–3,538,334, 35 genes, copy number 5 (within-gene range 2–5): SGTA, THOP1, ZNF554, ZNF555, AC006130.1, AC006130.3, ZNF556, AC006130.2, AC119403.2, ZNF57, AC119403.1, ZNF77, AC006277.1, TLE6, TLE2, AC005944.1, TLE5, GNA11, AC005262.2, KF456478.1, AC005262.1, GNA15, AC005264.1, S1PR4, NCLN, CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1.
- chr19:6,952,500–8,981,342, 99 genes, copy number 6 (broad region; genes not listed).
- chr19:10,651,862–17,871,705, 419 genes, copy number 6 (broad region; genes not listed).
- chr19:18,097,793–22,010,949, 192 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:4,120,980–4,249,287, 3 genes, copy number 7: SMOX, LINC01433, ADRA1D.
- chr20:4,627,758–5,197,887, 20 genes, copy number 8 (within-gene range 4–8): RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2.
- chr20:5,950,949–6,039,856, 1 gene, copy number 7 (within-gene range 4–7): AL035461.3.
- chr20:5,990,943–6,528,459, 12 genes, copy number 7: MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20.
- chr20:13,368,291–13,996,443, 7 genes, copy number 6: AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,003,699, 1 gene, copy number 6: RPS3P1.
- chr20:14,547,184–14,929,528, 4 genes, copy number 6: RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
